MMRF case MMRF_1523 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/60810d09-fee2-42a5-bd4a-865337ceeac5

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 59 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 59.5 years (21,726 days); ISS stage: II; Days to last known disease status: 1,279 days (3.5 years); Days to last follow up: 1,279 days (3.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 41 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 44 days.
   Treatment given: Therapeutic agents: Cyclophosphamide + Dexamethasone + Other; Regimen or line of therapy: First line of therapy; Days to treatment start: 79 days; Days to treatment end: 79 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 103 days; Days to treatment end: 103 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 104 days; Days to treatment end: 104 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 250 days; Days to treatment end: 259 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 258 days; Days to treatment end: 258 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 261 days; Days to treatment end: 261 days.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 0 (ECOG 1): M Protein 0.25 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 717 mg/dL; Immunoglobulin G 2.79 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.05 g/L; Beta 2 Microglobulin 5.01 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 5.27 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 272 ×10⁹/L; Creatinine 93.7 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 5.7 g/dL; Glucose 5.28 mmol/L.
- Day 99 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.09 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 20.4 mg/dL; Immunoglobulin G 3.77 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.2 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 8.87 µkat/L; Hemoglobin 5.77 mmol/L; Leukocytes 3.9 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 181 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.1 mmol/L; Albumin 36 g/L; Total Protein 5.6 g/dL; Glucose 5.5 mmol/L.
- Day 188 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.053 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.62 mg/dL; Immunoglobulin G 3.06 g/L; Immunoglobulin A 0.16 g/L; Immunoglobulin M 0.07 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 3.5 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 190 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.1 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 5.83 mmol/L.
- Day 282 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.36 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 4.87 mg/dL; Immunoglobulin G 6.93 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.15 g/L; Beta 2 Microglobulin 2.4 µg/mL; Hemoglobin 7.13 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 95 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 1.98 mmol/L; Albumin 30 g/L; Total Protein 5.3 g/dL; Glucose 6.27 mmol/L.
- Day 363 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.06 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.13 mg/dL; Immunoglobulin G 2.23 g/L; Immunoglobulin A 0.06 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 15.8 µkat/L; Hemoglobin 6.51 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 6 g/dL; Glucose 4.95 mmol/L.
- Day 453 (ECOG 2): M Protein 0.09 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.757 mg/dL; Immunoglobulin G 2.72 g/L; Immunoglobulin A 0.15 g/L; Immunoglobulin M 0.41 g/L; Beta 2 Microglobulin 2.18 µg/mL; Lactate Dehydrogenase 3.02 µkat/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.38 mmol/L; Albumin 43 g/L; Total Protein 5.8 g/dL; Glucose 4.79 mmol/L.
- Day 544 (ECOG 1): Hemoglobin 7.81 mmol/L; Leukocytes 5 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 147 ×10⁹/L.
- Day 629 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.727 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 6.41 g/L; Immunoglobulin A 0.68 g/L; Immunoglobulin M 0.56 g/L; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 48 g/L; Total Protein 6.8 g/dL; Glucose 5.28 mmol/L.
- Day 728 (ECOG 1): Hemoglobin 8 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 150 ×10⁹/L.
- Day 817 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.637 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.14 mg/dL; Immunoglobulin G 5.7 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.43 g/L; Lactate Dehydrogenase 2.43 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.25 mmol/L; Albumin 44 g/L; Total Protein 6.2 g/dL; Glucose 6.55 mmol/L.
- Day 915 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.674 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.11 mg/dL; Immunoglobulin G 5.84 g/L; Immunoglobulin A 0.62 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.83 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 46 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 1,006 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.847 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.55 mg/dL; Immunoglobulin G 5.5 g/L; Immunoglobulin A 0.78 g/L; Immunoglobulin M 0.52 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 2.68 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.33 mmol/L; Albumin 47 g/L; Total Protein 6.6 g/dL; Glucose 5.89 mmol/L.
- Day 1,097 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 1.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.95 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 1.18 g/L; Immunoglobulin M 0.54 g/L; Lactate Dehydrogenase 2.77 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 189 ×10⁹/L; Creatinine 86.6 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.2 mmol/L; Albumin 41 g/L; Total Protein 6.4 g/dL; Glucose 6.22 mmol/L.
- Day 1,189 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.933 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.28 mg/dL; Immunoglobulin G 6.91 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.49 g/L; Lactate Dehydrogenase 2.67 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 144 ×10⁹/L; Creatinine 83.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.4 mmol/L; Albumin 47 g/L; Total Protein 6.5 g/dL; Glucose 6.05 mmol/L.
- Day 1,279 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.912 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.32 mg/dL; Immunoglobulin G 6.7 g/L; Immunoglobulin A 1.32 g/L; Immunoglobulin M 0.45 g/L; Lactate Dehydrogenase 3.1 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 136 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 45 g/L; Total Protein 6.8 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day 0: Weight: 82 kg; Height: 190 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Colorectal Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_1523_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 0 days.
- Sample MMRF_1523_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 0 days.
